Somatic mutation profile of tumor specimen TCGA-B6-A0IA-01A (aliquot TCGA-B6-A0IA-01A-11W-A050-09) from TCGA case TCGA-B6-A0IA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.3 years (18,748 days).
Specimen TCGA-B6-A0IA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b00beb2c-9909-44ee-a4ae-ad80341f68c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IA-10A (Blood Derived Normal), aliquot TCGA-B6-A0IA-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88869b00-1b03-45ec-8d0a-a95f2e5900e9

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 15, Silent 8, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFTPH | c.502T>G p.L168V | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.164); catalogued as COSV53219708; called by muse, mutect2, varscan2
- DDIT3 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 24/273 reads (9%) | catalogued as COSV100007248; called by muse, mutect2
- FAM219A | c.422T>C p.I141T (on ENST00000445726; = p.I124T on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV52621523; called by muse, mutect2, varscan2
- GPSM2 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs867670266, COSV51443477; called by muse, mutect2, varscan2
- LDHC | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 43/394 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55004993; called by muse, mutect2, varscan2
- LEPR | c.2861G>T p.C954F | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758422493, COSV100848101, COSV62745270; called by muse, mutect2
- LRP12 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV52629057; called by muse, mutect2, varscan2
- MYF5 | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99079017, COSV99953228; called by muse, mutect2
- NOTCH1 | c.7195C>T p.P2399S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.041); catalogued as COSV99486845; called by muse, mutect2
- OBSCN | c.11398C>T p.L3800= | Splice Region (SNP) | VAF 13/253 reads (5%) | catalogued as COSV99476102; called by muse, mutect2
- PCDHB12 | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs556781909, COSV53393598; called by muse, mutect2, varscan2
- PCDHB7 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99176736; called by muse, mutect2, varscan2
- SCP2D1 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53857942; called by muse, mutect2, varscan2
- SIM1 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 55/72 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53494173; called by muse, mutect2, varscan2
- TIGD2 | c.755A>G p.Q252R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV100392318; called by muse, mutect2, varscan2
- TTN | c.98874del p.R32958Sfs*7 (on ENST00000591111; = p.R25534Sfs*7 on NM_003319.4) | Frame Shift Del (DEL) | VAF 55/224 reads (25%) | catalogued as COSV60179798; called by mutect2, pindel, varscan2
- WSCD2 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as rs749318050, COSV54586324; called by muse, mutect2, varscan2
- ZWILCH | c.1082T>A p.I361N | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV57181455; called by muse, mutect2, varscan2
- ATP1B1 | c.6C>G p.A2= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63179651; called by muse, mutect2, varscan2
- CACNA1C | c.1683G>A p.K561= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1203726409, COSV59742037; called by muse, mutect2, varscan2
- CDCA2 | c.1692G>A p.K564= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100398822; called by muse, mutect2, varscan2
- CNGB3 | c.1593G>A p.Q531= | Silent (SNP) | VAF 46/240 reads (19%) | catalogued as rs1379641710, COSV60693251; called by muse, mutect2, varscan2
- GRM6 | c.1389C>T p.N463= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs139745015; called by muse, mutect2, varscan2
- NEIL3 | c.1131C>T p.V377= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV52811953; called by muse, mutect2, varscan2
- PCDHB3 | c.1377C>T p.F459= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV50568585; called by muse, mutect2, varscan2
- TSPAN9 | c.411C>T p.A137= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV99170849; called by muse, mutect2
